Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A45T, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A45T-01A (Primary Tumor).

[page 1 of 2]
DOB:

Sex: F

Physician:

Accession:

Received:

Pathologist:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) RIGHT LARYNX, BIOPSY:
Squamous mucosa with hyperkeratosis, negative for dysplasia.
- (B) SUBMENTAL LYMPH NODE, BIOPSY:
One lymph node, no tumor present.
- (C) EXTERNAL JUGULAR LYMPH NODE:
One lymph node, no tumor present.
Salivary tissue, no tumor present.
- (D) LOWER JUGULAR LYMPH NODE:
Three lymph nodes, no tumor present.
- (E) RIGHT NECK DISSECTION, LEVEL I:
Five lymph nodes, no tumor present.
Salivary tissue, no tumor present.
- (F) RIGHT NECK DISSECTION, LEVEL II:
Three lymph nodes, no tumor present.
- (G) RIGHT NECK DISSECTION, LEVEL III:
Six lymph nodes, no tumor present.
- (H) RIGHT NECK DISSECTION, UPPER V:
Six lymph nodes, no tumor present.
- (I) RIGHT NECK DISSECTION, MIDDLE AND LOWER V:
Seven lymph nodes, no tumor present.
- (J) TONGUE, RIGHT PARTIAL GLOSSECTOMY:
INVASIVE SQUAMOUS CARCINOMA, POORLY DIFFERENTIATED INVOLVING TONGUE.
(SEE COMMENT)
TUMOR INVADES 0.7 CM IN DEPTH.
POSTERIOR MARGIN OF RESECTION POSITIVE FOR CARCINOMA.
Remaining margins of resection negative for carcinoma.
No lymph/vascular invasion identified.

ICD-0-3
Carcinoma, squamous cell 8070/3
Site: Tongue, Nos C02.9

lw
10/1/12

Entire report and diagnosis completed by :
Report released by:

COMMENT

The squamous carcinoma involving the tongue measures 1.7 cm in maximum dimension and invades to a depth of 0.7 cm. Tumor is present at the posterior resection margin. A total of 32 lymph nodes are negative for metastatic carcinoma.

GROSS DESCRIPTION

- (A) BIOPSY RIGHT LARYNX - A 0.2 x 0.1 x 0.1 cm fragment of tan tissue.
SECTION CODE: A, entire specimen.
- (B) SUBMENTAL LYMPH NODE - A 0.3 x 0.2 x 0.2 cm piece of tan tissue.

[page 2 of 2]
DOB:
Physician:

Sex: F

Received

Pathologist:

Accession:

Case type: Surgical History

SECTION CODE: B, entire specimen.

(C) EXTERNAL JUGULAR LYMPH NODE - A 3.0 x 1.5 x 0.6 cm piece of adipose tissue. Three possible lymph nodes are found, ranging in maximum dimension from 0.3 to 0.7 cm. No gross tumor is found.

SECTION CODE: C1, two possible lymph nodes; C2, one possible lymph node.

(D) LOWER JUGULAR NODE - A 2.7 x 1.5 x 0.6 cm piece of adipose tissue. Three possible lymph nodes are found, ranging in maximum dimension from 0.2 to 1.0 cm.

SECTION CODE: D1, one bisected lymph node; D2, one bisected lymph node; D3, one possible lymph node.

(E) RIGHT LEVEL I - A 5.5 x 2.5 x 1.0 cm piece of adipose tissue with attached 3.8 x 2.5 x 1.3 cm submandibular gland. Five possible lymph nodes are found, ranging in maximum dimension from 0.3 to 1.0 cm. No gross tumor is seen. No lesion is seen in the submandibular gland.

SECTION CODE: E1, submandibular gland; E2-E5, one bisected lymph node in each cassette; E6, one lymph node.

(F) RIGHT LEVEL II - A 3.2 x 2.0 x 1.0 cm piece of adipose tissue. Three lymph nodes are found, ranging in maximum dimension from 0.6 to 2.3 cm. No gross tumor is seen.

SECTION CODE: F1-F3, one bisected lymph node in each cassette.

(G) RIGHT LEVEL III - Two pieces of adipose tissue ranging in maximum dimension from 2.7 to 3.2 cm. Six possible lymph nodes are found, ranging in maximum dimension from 0.3 to 0.9 cm.

SECTION CODE: G1, three lymph nodes; G2, three lymph nodes.

(H) RIGHT UPPER V - A 2.7 x 2.0 x 1.0 cm piece of adipose tissue. Six possible lymph nodes are found, ranging in maximum dimension from 0.4 to 1.0 cm.

SECTION CODE: H1, one bisected lymph node; H2, one bisected lymph node; H3, four lymph nodes.

(I) RIGHT MIDDLE AND LOWER V - A 4.4 x 2.1 x 1.0 cm piece of adipose tissue. Eight possible lymph nodes are found, ranging in maximum dimension from 0.3 to 1.7 cm.

SECTION CODE: I1-I3, one bisected lymph node in each cassette; I4, two lymph nodes; I5, three lymph nodes.

(J) RIGHT PARTIAL GLOSSECTOMY - A 4.0 x 2.5 x 0.7 cm portion of tongue oriented by the surgeon. A central tan-white tumor nodule is present (1.7 x 1.5 x 0.4 cm) with ulceration. Tumor measures 0.2 cm from the nearest deep margin. The peripheral margins of resection are grossly negative. Focal leukoplakia is present along the mid inferior margin.

INK CODE: Black - deep; green - inferior; yellow - superior and blue - anterior; red - superior/anterior.

SECTION CODE: Entirely submitted from anterior to posterior as J1-J8.

SNOMED CODES

M-80703 T-53000

Page 2 of 2

History Case Pathology Report
File under: Pathology

History Case Pathology

Source: NCI Genomic Data Commons file ad424aa9-3aa0-480a-a909-e074f328ee9f (TCGA-CV-A45T.0100694A-4209-41E7-B569-D256D34DB76A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).